Somatic mutation profile of tumor specimen TARGET-10-PAPJIB-04A (aliquot TARGET-10-PAPJIB-04A-01D) from TARGET case TARGET-10-PAPJIB, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.5 years (903 days).
Specimen TARGET-10-PAPJIB-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b50b5f9b-849a-4f2d-abe5-195ec952cc91.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PAPJIB-14A (Bone Marrow Normal), aliquot TARGET-10-PAPJIB-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d36622c5-c489-4399-8394-b76b4804a02a

The open-access MAF lists 30 somatic variants for this specimen: 21 protein-altering or splice-affecting, 7 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Splice Site 1, Intron 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS9 | c.1789+1G>A p.X597_splice (on ENST00000242067 / NM_001348036.1; = p.X557_splice on NM_014451.3 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 44/571 reads (8%) | catalogued as rs201938124, CS055613, COSV54176338; ClinVar: pathogenic; called by muse, mutect2
- CREBBP | c.4337G>A p.R1446H | Missense Mutation (SNP) | VAF 170/340 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1057519884, COSV52112787, COSV52125401, COSV52132241; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 80/363 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADGRD2 | c.220C>T p.R74W | Missense Mutation (SNP) | VAF 13/39 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); catalogued as COSV58341160; called by muse, mutect2, varscan2
- ALG13 | c.2686G>A p.G896S | Missense Mutation (SNP) | VAF 33/448 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.031); catalogued as rs972892187, COSV52638954; ClinVar: uncertain significance; called by muse, mutect2
- ASXL3 | c.1003C>G p.R335G | Missense Mutation (SNP) | VAF 54/492 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV52471978, COSV52475965, COSV99324572; called by muse, varscan2
- DBT | c.533G>A p.R178H | Missense Mutation (SNP) | VAF 123/430 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs139251881; called by mutect2, varscan2
- DNAH9 | c.12292G>A p.A4098T | Missense Mutation (SNP) | VAF 65/258 reads (25%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs201738395, COSV52358699; called by muse, mutect2, varscan2
- FBN1 | c.157C>A p.L53I | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as COSV57323028; called by muse, mutect2, varscan2
- ITPRIPL2 | c.1540C>T p.R514C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV67347871, COSV67348035; called by muse, mutect2, varscan2
- MSH6 | c.3014G>A p.R1005Q | Missense Mutation (SNP) | VAF 25/224 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs587782324, COSV52283146; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MUC4 | c.12428C>T p.T4143M | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); catalogued as rs1395634435; called by muse, varscan2
- NT5C2 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 11/348 reads (3%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as rs1057519866, COSV58414509; ClinVar: not provided; called by muse, mutect2
- OR11H1 | c.170G>C p.R57P | Missense Mutation (SNP) | VAF 33/350 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53272035, COSV53272189; called by muse, mutect2
- RRAGB | c.614G>C p.R205P (on ENST00000262850 / NM_016656.4; = p.R177P on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/1288 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53330620; called by muse, mutect2
- SLC12A2 | c.1777A>G p.M593V | Missense Mutation (SNP) | VAF 108/520 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.577); catalogued as COSV52473541; called by muse, varscan2
- SLC30A5 | c.1027G>A p.V343I | Missense Mutation (SNP) | VAF 58/620 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.437); catalogued as rs145568710; called by muse, mutect2
- TGFBRAP1 | c.1196G>A p.R399Q | Missense Mutation (SNP) | VAF 13/224 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.526); catalogued as rs895448764, COSV51511631; called by muse, mutect2
- TRIP12 | c.3730G>A p.G1244R | Missense Mutation (SNP) | VAF 14/194 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV52267861; called by muse, mutect2
- VRK2 | c.1477A>G p.I493V | Missense Mutation (SNP) | VAF 116/1026 reads (11%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1275459390, COSV52075874; called by muse, varscan2
- RRAGB | c.613C>G p.R205G (on ENST00000262850 / NM_016656.4; = p.R177G on NM_006064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/1280 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); called by muse, mutect2
- ABCC3 | c.120G>A p.V40= | Silent (SNP) | VAF 41/205 reads (20%) | catalogued as COSV53325210; called by muse, mutect2, varscan2
- EBF2 | c.879C>T p.S293= | Silent (SNP) | VAF 23/196 reads (12%) | catalogued as rs369804649; called by muse, mutect2, varscan2
- FAM155A | c.75C>T p.N25= | Silent (SNP) | VAF 27/108 reads (25%) | catalogued as COSV65572179; called by muse, mutect2, varscan2
- PPM1H | c.924C>T p.P308= | Silent (SNP) | VAF 37/179 reads (21%) | catalogued as rs571729631, COSV57376658; called by muse, mutect2, varscan2
- PSMG3 | c.39G>A p.T13= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs780097745, COSV52920741, COSV52920757; called by muse, mutect2
- SLC2A4 | c.438C>T p.G146= | Silent (SNP) | VAF 21/82 reads (26%) | catalogued as rs1232209607, COSV50301528; called by muse, mutect2, varscan2
- TPSG1 | c.261C>T p.S87= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs757499850; called by muse, varscan2
- SHANK2 | c.1174+33079C>T | Intron (SNP) | VAF 22/91 reads (24%) | catalogued as rs934627063, COSV99573390; called by muse, mutect2, varscan2
- ZNF98 | c.-5C>T | 5'UTR (SNP) | VAF 22/78 reads (28%) | catalogued as COSV100757611, COSV63337956; called by muse, mutect2, varscan2
